Gene-level copy-number profile of tumor specimen TCGA-22-4607-01A from TCGA case TCGA-22-4607, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 75.6 years (27,601 days).
Specimen TCGA-22-4607-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.3f6a0685-0cb8-4497-a6ce-f06dc9e83e39.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-4607-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bec66415-2a4b-484c-b0a0-d702d56893bb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 16,805; copy number 2: 35,829; copy number 3: 6,753; copy number 4: 2; copy number 6: 258; copy number 8: 40; copy number 10: 101; copy number 13: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-4607-01A-01D-1195-01): tumor purity 0.63, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 429 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:6,887,566–6,940,459, 1 gene, copy number 10 (within-gene range 1–10): ADGRE1.
- chr19:6,928,345–14,496,149, 428 genes, copy number 6–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,418. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
